Gene-level copy-number profile of tumor specimen TCGA-61-1918-01A from TCGA case TCGA-61-1918, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 45.7 years (16,689 days).
Specimen TCGA-61-1918-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.eaa038ef-a98e-4cae-a8b2-11d6afd9991c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1918-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef56977f-157b-4f97-9c5a-c9434f32c7f1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 421; copy number 2: 9,760; copy number 3: 21,906; copy number 4: 18,092; copy number 5: 5,748; copy number 6: 1,944; copy number 7: 792; copy number 8: 541; copy number 9: 300; copy number 10: 121; copy number 11: 98; copy number 13: 82.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-61-1918-01): tumor purity 0.8, ploidy 3.4, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,915 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,895,761–11,691,650, 29 genes, copy number 7: HSPE1P24, C1orf127, CFL1P6, TARDBP, AL109811.3, MASP2, AL109811.2, SRM, EXOSC10, AL109811.1, EXOSC10-AS1, MTOR, MTOR-AS1, RNU6-537P, ANGPTL7, RNU6-291P, RPL39P6, UBIAD1, UBE2V2P3, AL031291.1, MTCYBP45, DISP3, AL590989.1, LINC01647, AL031731.1, FBXO2, FBXO44, FBXO6, MAD2L2.
- chr1:35,399,997–45,015,575, 321 genes, copy number 7–10 (broad region; genes not listed).
- chr1:45,069,977–45,070,429, 1 gene, copy number 7: OSTCP5.
- chr1:143,343,180–154,580,013, 502 genes, copy number 7–13 (broad region; genes not listed).
- chr1:189,666,149–192,011,260, 19 genes, copy number 7–8: RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1.
- chr2:215,436,253–216,220,192, 19 genes, copy number 7: AC012462.3, AC012462.1, AC012462.2, AC012668.2, AC012668.3, AC012668.1, LINC00607, LINC01614, AC093850.1, AC122136.1, AC093382.1, MREG, PECR, TMEM169, XRCC5, POLHP1, AC012513.2, AC012513.3, LINC01963.
- chr2:216,259,595–216,321,737, 2 genes, copy number 7 (within-gene range 4–7): AC012513.1, AC069155.1.
- chr3:58,162,547–58,666,834, 20 genes, copy number 9: FLNB-AS1, AC137936.1, AC137936.2, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1, FAM107A, AC119424.1, FAM3D-AS1, FAM3D.
- chr3:65,174,916–67,654,612, 23 genes, copy number 7–8 (within-gene range 6–8): LINC02040, MAGI1, AC121493.1, ILF2P1, RPL17P17, MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1, SLC25A26, RNU6-787P, RN7SL482P, LRIG1, AC104440.1, RPL21P41, AC098969.2, AC098969.1, AC020655.1, KBTBD8, MIR4272, AC114401.1, SUCLG2, NDUFB4P1.
- chr3:68,004,247–69,542,583, 16 genes, copy number 7–9 (within-gene range 4–9): TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B.
- chr3:78,597,239–79,767,998, 3 genes, copy number 8 (within-gene range 5–8): ROBO1, AC055731.1, RN7SL751P.
- chr3:145,523,538–149,752,495, 71 genes, copy number 7–8 (broad region; genes not listed).
- chr3:149,779,009–149,779,108, 1 gene, copy number 7: RNU6-507P.
- chr3:167,956,311–196,287,957, 525 genes, copy number 8–11 (within-gene range 5–11) (broad region; genes not listed).
- chr3:196,250,542–196,251,654, 1 gene, copy number 9: AC069257.1.
- chr6:14,431,683–18,155,077, 51 genes, copy number 7 (within-gene range 4–7): AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1, ARPC3P5, LINC02543, AL365265.1, MDH1P2, MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1, ATXN1, ATXN1-AS1, AL137003.1, AL133405.2, AL133405.1, AL138740.1, STMND1, AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT.
- chr6:34,279,679–37,819,218, 104 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr7:876,554–2,251,146, 38 genes, copy number 8: GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655, MRM2, NUDT1.
- chr7:2,257,515–2,257,577, 1 gene, copy number 8: MIR6836.
- chr7:20,959,391–21,221,428, 3 genes, copy number 7: AC080068.1, RN7SL542P, ASS1P11.
- chr8:30,192,429–32,855,666, 39 genes, copy number 7 (within-gene range 5–7): AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3, AC068672.1, AC090816.1, RNA5SP261, NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1.
- chr8:94,487,689–94,793,836, 13 genes, copy number 7 (within-gene range 4–7): VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4.
- chr8:104,590,733–105,804,539, 1 gene, copy number 7 (within-gene range 6–7): ZFPM2.
- chr8:105,142,860–106,770,244, 17 genes, copy number 7: AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA.
- chr8:127,072,694–127,227,541, 1 gene, copy number 7 (within-gene range 5–7): CASC19.
- chr8:127,253,213–129,683,770, 27 genes, copy number 7 (within-gene range 6–7): AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206.
- chr13:108,251,240–108,308,484, 1 gene, copy number 9 (within-gene range 5–9): TNFSF13B.
- chr13:108,301,212–108,481,817, 3 genes, copy number 9: RNA5SP39, AL138694.1, HCFC2P1.
- chr16:70,802,084–71,230,722, 4 genes, copy number 7 (within-gene range 4–7): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr19:28,435,388–28,727,680, 1 gene, copy number 7 (within-gene range 6–7): AC005394.2.
- chr19:28,602,379–31,787,255, 58 genes, copy number 7: AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P.

Autosomal genes at a single copy (total copy number 1): 421. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
